Surgical pathology report (de-identified scan), TCGA case TCGA-Z4-AAPG, project TCGA-SARC (Sarcoma), tissue source site Cureline, specimen TCGA-Z4-AAPG-01A (Primary Tumor).

Case #

Patient: **Age (years):** **Gender:** F

Clinical diagnosis: Sarcoma

Date of procurement: (mm/dd/yyyy)

Sample:

Gross description: Soft tissue from retroperitoneum measured 10x10x7 cm with subcutaneous adipose tissue 2 cm thick.. Section shows tumor mass in retroperitoneum

Microscopic description: Sections reveal the tumor cells that are characterized by high cellularity with marked nuclear pleomorphism. Surgical margins are clear. Histology consistent with Undifferentiated Pleomorphic Sarcoma, Grade 3

Final diagnosis: Undifferentiated Pleomorphic Sarcoma

ICD-O-3
Sarcoma, undifferentiated,
pleomorphic (8805/3)
(8802/3) Code to highest 8805/3
Site: Retroperitoneum (48.0)
JSD 4/22/14

Confidential

Source: NCI Genomic Data Commons file 9ac01def-d883-4b45-a126-007feb51f15c (TCGA-Z4-AAPG.D1D4CCF2-6C30-4BF3-85FC-32DA3AD03F93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).